Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAE6, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAE6-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: R/O HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation:

Left hemihepatectomy

Cholecystectomy

Organs:

Liver (21.5 x 14.0 x 6.0 cm, 485.5 gm)

Gallbladder (10.7 cm in length, 2.6 cm in diameter, and 0.3 cm in thickness)

Lesion:

[Liver]

Multinodular conglomerated tumor mass (11.0 x 10.5 x 5.5 cm)

Cut surface: Yellowish tan and solid with area of necrosis

Gross type:

HCC: Multinodular confluent

Resection margin: Not involved grossly (safety margin: 7.0 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Cirrhotic

[Gallbladder]

No stone

Representative sections submitted

Gross photo: Present

Blocks

TB, T1-5, tumor mass x 6

L,NB, liver parenchyma x 2

RM, resection margin x 1

GB. gallbladder x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation II

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: No

Septum formation: Yes

Surgical resection margin invasion: No

Serosal invasion: No

TCDD-3

Carcinoma, hepatocellular NOS
8170/3

Date: Liver 122.0

940 5/20/14

[page 2 of 2]
Portal vein invasion: Yes
Microvessel invasion: Yes
Intrahepatic metastasis: Yes
Multicentric occurrence: Yes

NOT reported. Gross:

Liver, left, ectomy, hepatocellular carcinoma, moderately differentiated
T56000, left, P10, M81703, moderately differentiated
Gallbladder, ectomy, chronic cholecystitis
T57000, P10, M43005

DIAGNOSIS:

Liver, segment 2, left hemihepatectomy:
Hepatocellular carcinoma, moderately differentiated

Gallbladder, cholecystectomy:
Chronic cholecystitis

Suggestion :

Source: NCI Genomic Data Commons file a5fb513f-1138-43e2-a832-6ed1fe20a3ed (TCGA-DD-AAE6.1B3F62E9-8E87-43FA-AEA8-00C89D678F8F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).